Somatic mutation profile of tumor specimen ALCH-B1H6-TTP1-A (aliquot ALCH-B1H6-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1H6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.7 years (28,379 days).
Specimen ALCH-B1H6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d84101e-3030-483e-b1de-bae633bab915.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1H6-NB1-A (Blood Derived Normal), aliquot ALCH-B1H6-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79587020-c523-436d-bae6-6334650b15d7

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Splice Site 2, Nonsense Mutation 2, 5'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 37/530 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 48/633 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- BRWD1 | c.1263G>C p.E421D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs753152900; called by muse, varscan2
- DIPK1C | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs905697242; called by muse, mutect2
- G6PD | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782674059, COSV63704386; called by muse, mutect2
- GDF10 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535252557; called by muse, mutect2, varscan2
- KCNH4 | c.1915G>A p.V639M | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs564497876; called by muse, mutect2
- RASA2 | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99656746; called by muse, mutect2
- SETD3 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1261336639, COSV59286859; called by muse, mutect2
- AIMP2 | c.136-2A>T p.X46_splice | Splice Site (SNP) | VAF 18/273 reads (7%) | called by muse, mutect2
- ALOX15B | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ATM | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- ATM | c.5542G>T p.D1848Y | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BRMS1 | c.439-1G>C p.X147_splice | Splice Site (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- DNAH9 | c.7849T>C p.F2617L | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- EVI2B | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- IGKV3-11 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 23/481 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.085); called by muse, mutect2
- MED12 | c.5977C>T p.Q1993* | Nonsense Mutation (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- OR11L1 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- PCDHB2 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.152); called by muse, mutect2
- PLAGL2 | c.785del p.C262Sfs*7 | Frame Shift Del (DEL) | VAF 88/558 reads (16%) | called by mutect2, pindel, varscan2
- QRICH2 | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2
- RASSF9 | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- RBM33 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 31/674 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.427); called by muse, mutect2
- SLC35F4 | c.619A>T p.I207F (on ENST00000339762 / NM_001352015.2; = p.I171F on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.042); called by muse, mutect2
- SP1 | c.692T>C p.L231P (on ENST00000327443 / NM_138473.3; = p.L224P on NM_003109.1) | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- VAV1 | c.1121A>T p.K374M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WAPL | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZHX2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.335); called by muse, mutect2
- ZNF256 | c.1598G>T p.S533I | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.26); called by muse, mutect2
- HRNR | c.6036T>C p.H2012= | Silent (SNP) | VAF 48/786 reads (6%) | catalogued as rs1269214277; called by muse, mutect2
- PIWIL1 | c.1632C>T p.V544= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- SLC4A4 | c.543G>A p.Q181= (on ENST00000264485 / NM_001098484.3; = p.Q137= on NM_003759.4) | Silent (SNP) | VAF 26/594 reads (4%) | called by muse, mutect2
- TRPC4AP | c.606G>A p.K202= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as COSV52681532; called by muse, mutect2, varscan2
- USP6 | c.1311G>A p.L437= | Silent (SNP) | VAF 41/696 reads (6%) | called by muse, mutect2
- VANGL1 | c.21T>C p.Y7= | Silent (SNP) | VAF 40/733 reads (5%) | called by muse, mutect2
- CUEDC2 | chr10:102436516 G>T | 5'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- RELT | c.626-152A>G | Intron (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
